Somatic mutation profile of tumor specimen MMRF_1858_1_BM_CD138pos (aliquot MMRF_1858_1_BM_CD138pos_T1_KBS5U_L05815) from MMRF case MMRF_1858, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.8 years (22,939 days).
Specimen MMRF_1858_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27507062-cd30-406e-a0e6-617c46a07b29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1858_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1858_1_PB_Whole_C2_KBS5U_L05829; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9379894-9572-4a8a-a59d-00349d77a0aa

The open-access MAF lists 103 somatic variants for this specimen: 35 protein-altering or splice-affecting, 16 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 32, Missense Mutation 28, Intron 16, Silent 16, Nonsense Mutation 5, RNA 2, 5'UTR 1, 5'Flank 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 48/50 reads (96%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATG9B | c.2698C>T p.R900W | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs752565788; called by muse, mutect2, varscan2
- CCIN | c.1011G>T p.E337D | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.982); catalogued as COSV58724584; called by muse, mutect2, varscan2
- IGHV2-70D | c.98C>G p.P33R | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1280161406; called by muse, varscan2
- KIF26A | c.4355G>A p.R1452Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs749540148, COSV59466299; called by muse, mutect2, varscan2
- KRT72 | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs1461072774; called by muse, mutect2, varscan2
- LGI2 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs149130054; called by muse, mutect2, varscan2
- MYT1L | c.3359C>T p.A1120V | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101216703, COSV101217154; called by muse, mutect2, varscan2
- PSPC1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); catalogued as rs1433781701; called by muse, mutect2, varscan2
- PTPRS | c.4145C>T p.T1382M | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as rs558948003, COSV53634267; called by muse, mutect2, varscan2
- RB1 | c.1004T>A p.L335* | Nonsense Mutation (SNP) | VAF 17/18 reads (94%) | catalogued as COSV57294419, COSV57296214; called by muse, mutect2, varscan2
- SNTG2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs185149623; called by muse, mutect2, varscan2
- TGIF2LX | c.-22+1G>A | Splice Site (SNP) | VAF 115/124 reads (93%) | catalogued as COSV99033352; called by muse, mutect2, varscan2
- ZNF549 | c.1025G>A p.R342H (on ENST00000376233 / NM_001199295.2; = p.R329H on NM_153263.2) | Missense Mutation (SNP) | VAF 146/235 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.392); catalogued as rs374746805; called by muse, mutect2, varscan2
- ANO4 | c.1000C>A p.Q334K (on ENST00000392977 / NM_001286615.2; = p.Q299K on NM_178826.4) | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ARHGEF17 | c.1747C>A p.L583M | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CDK12 | c.1874C>A p.S625* | Nonsense Mutation (SNP) | VAF 16/173 reads (9%) | called by muse, mutect2
- CHRFAM7A | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by mutect2, varscan2
- GPT2 | c.1309_1314del p.G437_A438del | In Frame Del (DEL) | VAF 14/143 reads (10%) | called by mutect2, pindel
- IGHV2-70D | c.347G>C p.C116S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, varscan2
- IGHV2-70D | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, varscan2
- IGHV2-70D | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, varscan2
- IGHV2-70D | c.68T>A p.L23* | Nonsense Mutation (SNP) | VAF 33/126 reads (26%) | called by muse, varscan2
- LTB | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.018); called by muse, varscan2
- MEI1 | c.1635A>T p.E545D | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- PLAA | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PTPRN2 | c.2682C>G p.N894K | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO2 | c.3575A>C p.Q1192P | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- SELENOI | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- TM9SF3 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 91/165 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNKS | c.3386T>C p.I1129T | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- TRBV4-2 | c.261C>A p.C87* | Nonsense Mutation (SNP) | VAF 61/216 reads (28%) | called by muse, mutect2, varscan2
- VWA2 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 39/73 reads (53%) | called by muse, mutect2, varscan2
- YES1 | c.280A>C p.T94P | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ZFP57 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ACKR2 | c.30C>T p.L10= | Silent (SNP) | VAF 81/183 reads (44%) | called by muse, mutect2, varscan2
- AGR2 | c.402T>G p.S134= | Silent (SNP) | VAF 95/309 reads (31%) | called by muse, mutect2, varscan2
- AMFR | c.1353G>A p.Q451= | Silent (SNP) | VAF 33/44 reads (75%) | called by muse, mutect2, varscan2
- APBB3 | c.1107C>T p.R369= (on ENST00000357560 / NM_133173.2; = p.R376= on NM_006051.3) | Silent (SNP) | VAF 76/224 reads (34%) | catalogued as rs142416720; called by muse, mutect2, varscan2
- CEMIP | c.3324C>T p.G1108= | Silent (SNP) | VAF 73/212 reads (34%) | catalogued as rs763149229; called by muse, mutect2, varscan2
- GLYCTK | c.1518G>A p.G506= | Silent (SNP) | VAF 158/327 reads (48%) | catalogued as rs1251265660; called by muse, mutect2, varscan2
- GNAI2 | c.549G>A p.T183= | Silent (SNP) | VAF 57/122 reads (47%) | catalogued as rs1450299309, COSV99807179; called by muse, mutect2, varscan2
- GTF2A1 | c.660C>T p.I220= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV53336880; called by muse, mutect2, varscan2
- IGHV1-3 | c.72G>A p.V24= | Silent (SNP) | VAF 52/58 reads (90%) | catalogued as rs1236421773; called by muse, mutect2
- IGHV2-70D | c.327G>A p.V109= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, varscan2
- IGHV2-70D | c.120C>A p.T40= | Silent (SNP) | VAF 38/125 reads (30%) | called by muse, varscan2
- IGKC | c.156C>A p.S52= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- IL20RA | c.1413G>A p.P471= | Silent (SNP) | VAF 21/176 reads (12%) | catalogued as rs564258970; called by muse, mutect2, varscan2
- PDZRN4 | c.2475A>G p.E825= (on ENST00000402685 / NM_001164595.2; = p.E567= on NM_013377.4) | Silent (SNP) | VAF 15/163 reads (9%) | called by muse, mutect2
- SLC12A1 | c.1398C>T p.D466= | Silent (SNP) | VAF 97/161 reads (60%) | called by muse, mutect2, varscan2
- TIGD5 | c.1191C>T p.G397= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs781652798; called by muse, mutect2, varscan2
- ADAMTS15 | c.*527G>A | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.*1556G>C | 3'UTR (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- ADGRG3 | c.*625G>C | 3'UTR (SNP) | VAF 98/115 reads (85%) | called by muse, mutect2, varscan2
- BLOC1S5 | c.*1494G>A | 3'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- BMP5 | c.*302A>C | 3'UTR (SNP) | VAF 58/104 reads (56%) | called by muse, mutect2
- BMP6 | c.*748C>T | 3'UTR (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- C3orf49 | c.-65T>C | 5'UTR (SNP) | VAF 111/241 reads (46%) | catalogued as rs921640174; called by muse, mutect2, varscan2
- C7orf66 | n.86C>T | RNA (SNP) | VAF 121/389 reads (31%) | called by muse, mutect2, varscan2
- CCDC38 | c.370-11A>G | Intron (SNP) | VAF 44/95 reads (46%) | called by muse, mutect2, varscan2
- CCSER1 | c.2011-35131C>A | Intron (SNP) | VAF 11/81 reads (14%) | called by muse, varscan2
- CYBC1 | c.*517C>T | 3'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- CYP3A43 | c.433-14G>A | Intron (SNP) | VAF 49/154 reads (32%) | called by muse, mutect2, varscan2
- DPPA4 | c.*14del | 3'UTR (DEL) | VAF 6/16 reads (38%) | catalogued as rs1161174696, COSV59510977; called by pindel, varscan2
- EPHA10 | c.*2209T>C | 3'UTR (SNP) | VAF 52/107 reads (49%) | called by muse, mutect2, varscan2
- EYS | c.1766+4790G>T | Intron (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- GATA6 | c.*909G>A | 3'UTR (SNP) | VAF 52/146 reads (36%) | called by muse, mutect2, varscan2
- GATM | c.288+47C>A | Intron (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2
- GYG1 | c.*620A>G | 3'UTR (SNP) | VAF 5/73 reads (7%) | catalogued as rs941150799; called by muse, mutect2
- HGF | c.625+726A>C | Intron (SNP) | VAF 55/81 reads (68%) | called by muse, mutect2, varscan2
- HOXB13 | c.*823A>C | 3'UTR (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- HSP90AA1 | c.163-19T>G | Intron (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- IRX5 | c.250-52G>A | Intron (SNP) | VAF 54/63 reads (86%) | catalogued as rs759491659; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.702+18G>A | Intron (SNP) | VAF 89/143 reads (62%) | called by muse, mutect2, varscan2
- KCNAB3 | c.242+18C>A | Intron (SNP) | VAF 49/104 reads (47%) | called by muse, mutect2, varscan2
- KCNIP1 | chr5:170504411 C>T | 5'Flank (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- KHDC3L | c.*60C>T | 3'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- LTB | c.162+152T>C | Intron (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- MIR520F | n.21A>G | RNA (SNP) | VAF 89/138 reads (64%) | called by muse, mutect2, varscan2
- MLXIPL | c.573+120C>T | Intron (SNP) | VAF 11/176 reads (6%) | called by muse, mutect2
- MPI | c.*1341del | 3'UTR (DEL) | VAF 37/134 reads (28%) | called by mutect2, pindel, varscan2
- NBEAL1 | c.*2515_*2516insC | 3'UTR (INS) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- PARM1 | c.*3114A>T | 3'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- PARVA | c.*777A>G | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- PLCB4 | c.*842C>A | 3'UTR (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- PPM1H | c.*2328A>G | 3'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- PTGFRN | c.*144G>A | 3'UTR (SNP) | VAF 17/17 reads (100%) | catalogued as rs1253991850; called by muse, mutect2, varscan2
- RCC1 | c.-261-86C>T | Intron (SNP) | VAF 42/79 reads (53%) | catalogued as rs939090990, COSV63120771; called by muse, mutect2, varscan2
- RNF4 | c.*25A>G | 3'UTR (SNP) | VAF 119/312 reads (38%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*83A>C | 3'UTR (SNP) | VAF 78/84 reads (93%) | called by muse, mutect2, varscan2
- SIDT1 | c.1046-68C>A | Intron (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- SMG7 | c.*804G>T | 3'UTR (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- SMU1 | c.*1918C>T | 3'UTR (SNP) | VAF 19/65 reads (29%) | catalogued as rs527923652; called by muse, mutect2, varscan2
- ST8SIA1 | c.*178_*180del | 3'UTR (DEL) | VAF 52/112 reads (46%) | called by mutect2, pindel, varscan2
- SUSD6 | c.*2761G>C | 3'UTR (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- SV2C | c.*5760T>G | 3'UTR (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- TBCC | c.*322C>T | 3'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- TMEM251 | c.*478C>T | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- TMEM251 | c.*479C>T | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- TPPP3 | c.188+93A>G | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- UBASH3B | c.602-17T>C | Intron (SNP) | VAF 49/118 reads (42%) | called by muse, mutect2, varscan2
- VEPH1 | c.*543A>T | 3'UTR (SNP) | VAF 4/77 reads (5%) | called by muse, mutect2
- ZSCAN12 | c.*636C>A | 3'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
